Gene-level copy-number profile of tumor specimen TCGA-EO-A1Y7-01A from TCGA case TCGA-EO-A1Y7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 65.9 years (24,085 days).
Specimen TCGA-EO-A1Y7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.7f49942f-804b-48af-a0bc-7d7efdd90110.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EO-A1Y7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/49c757c1-8b4a-4dc8-8cdc-9af0ba50ac48

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 9,610; copy number 3: 2,793; copy number 4: 40,924; copy number 5: 1,251; copy number 6: 3,156; copy number 7: 684; copy number 8: 1,138; copy number 9: 37; copy number 10: 133; copy number 11: 9; copy number 12: 62; copy number 13: 12; copy number 29: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EO-A1Y7-01A-11D-A160-01): tumor purity 0.94, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 255 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:119,679,167–119,700,151, 2 genes, copy number 9: TMEM177, RPL17P15.
- chr3:48,372,219–48,898,904, 27 genes, copy number 9: FBXW12, RN7SL321P, PLXNB1, CCDC51, TMA7, AC134772.1, ATRIP, TREX1, SHISA5, PFKFB4, MIR6823, UCN2, COL7A1, MIR711, UQCRC1, TMEM89, SLC26A6, MIR6824, CELSR3, MIR4793, LINC02585, AC141002.1, NCKIPSD, IP6K2, PRKAR2A, PRKAR2A-AS1, SLC25A20.
- chr3:168,902,194–169,038,416, 4 genes, copy number 10: LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr7:45,391,626–45,542,182, 3 genes, copy number 13–29: ELK1P1, AC073325.1, AC073325.2.
- chr8:23,243,637–24,359,014, 22 genes, copy number 10 (within-gene range 3–10): CHMP7, R3HCC1, LOXL2, AC090197.1, ENTPD4, AC104561.1, AC104561.2, AC104561.4, AC104561.3, SLC25A37, RNU4-71P, SINHCAFP3, NKX3-1, NKX2-6, AC012574.1, AC012574.2, AC012119.2, AC012119.1, STC1, RNU1-148P, AC023202.1, ADAM28.
- chr8:24,384,285–24,526,970, 3 genes, copy number 10: ADAMDEC1, ADAM7, AC024958.1.
- chr8:39,743,735–40,520,158, 16 genes, copy number 10 (within-gene range 2–10): ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1.
- chr8:42,128,774–43,674,591, 54 genes, copy number 12: AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr8:54,130,582–54,394,870, 8 genes, copy number 12: Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1, AC044836.1, RNU105C, AC027250.1, AC027250.2.
- chr8:97,624,203–98,294,393, 19 genes, copy number 10 (within-gene range 8–10): AP002982.1, AP002982.2, MTDH, Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P.
- chr8:127,794,526–128,187,101, 1 gene, copy number 13 (within-gene range 7–13): PVT1.
- chr8:127,890,626–128,220,803, 10 genes, copy number 13: AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226.
- chr10:68,560,337–69,104,805, 20 genes, copy number 10 (within-gene range 6–10): TET1, COX20P1, RPS3AP37, AL513534.2, AL513534.3, CCAR1, Y_RNA, SNORD98, AL513534.1, STOX1, RNU6-697P, AL359844.1, DDX50, RNU6-571P, DDX21, KIFBP, MED28P1, ACTBP14, SRGN, Metazoa_SRP.
- chr12:55,973,913–56,144,674, 16 genes, copy number 9–10 (within-gene range 7–10): RAB5B, AC034102.1, SUOX, IKZF4, AC034102.8, AC034102.3, RPS26, ERBB3, AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6.
- chr14:39,147,811–39,388,513, 9 genes, copy number 11 (within-gene range 4–11): TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2.
- chr22:22,730,725–22,923,034, 41 genes, copy number 10: AC244250.3, IGLV2-18, IGLV3-17, IGLV3-16, IGLV3-15, IGLV2-14, IGLV3-13, IGLV3-12, AC244157.1, AC244157.2, IGLV2-11, AC245028.3, IGLV3-10, AC245028.1, IGLV3-9, IGLV2-8, MIR650, AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571, IGLL5, IGLJ1, IGLC1, IGLJ2, IGLC2, IGLJ3, IGLC3, IGLJ4, IGLC4, IGLJ5, IGLC5, IGLJ6, IGLC6, IGLJ7, IGLC7.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
